Somatic mutation profile of tumor specimen TCGA-04-1346-01A (aliquot TCGA-04-1346-01A-01W-0486-08) from TCGA case TCGA-04-1346, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 73.6 years (26,865 days).
Specimen TCGA-04-1346-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8aec2497-80e3-4711-ad79-0062e49ae4bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1346-11A (Solid Tissue Normal), aliquot TCGA-04-1346-11A-01W-0487-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05285bc8-faac-4119-8388-a2cf1c5d0b17

The open-access MAF lists 50 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 14, Frame Shift Del 2, In Frame Del 1, 5'UTR 1, Splice Site 1, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANLN | c.2804G>A p.R935Q | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462474727, COSV56074462; called by muse, mutect2, varscan2
- APLP1 | c.1787T>A p.L596H (on ENST00000221891 / NM_001024807.3; = p.L595H on NM_005166.4) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55704877; called by muse, mutect2
- CARMIL1 | c.3782C>T p.S1261F | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.309); catalogued as COSV61519950; called by muse, mutect2, varscan2
- CDH7 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59887000; called by muse, mutect2
- COL6A1 | c.2347C>G p.R783G | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV62611795, COSV62614078, COSV62614097; called by muse, mutect2
- CRTAM | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV57069177; called by muse, mutect2, varscan2
- DLC1 | c.1174-1G>A p.X392_splice | Splice Site (SNP) | VAF 44/171 reads (26%) | catalogued as COSV52312634; called by muse, mutect2, varscan2
- FERMT1 | c.1945G>A p.G649S | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs558908354, COSV54094657; called by muse, mutect2, varscan2
- GPR158 | c.3322C>T p.R1108C | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs372238950, COSV66267514; called by muse, mutect2, varscan2
- GRB7 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs373351063; called by muse, mutect2, varscan2
- GRID2 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56169233; called by muse, mutect2, varscan2
- HAL | c.1801G>C p.E601Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); catalogued as rs377498665, COSV54118686; called by muse, mutect2, varscan2
- HMGCR | c.829C>G p.P277A | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV55316544; called by muse, mutect2, varscan2
- IFT52 | c.1266G>T p.Q422H | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.807); catalogued as COSV65975439; called by muse, mutect2, varscan2
- ITIH3 | c.968T>C p.I323T | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV69649420; called by muse, mutect2, varscan2
- LAMA2 | c.7585G>A p.V2529I | Missense Mutation (SNP) | VAF 46/439 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV70351045; called by muse, mutect2, varscan2
- MAST1 | c.1245G>C p.Q415H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52249665; called by muse, mutect2, varscan2
- MED12L | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 120/1048 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV56385268; called by muse, varscan2
- MTERF4 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV99613033; called by muse, mutect2
- OBSL1 | c.4213G>A p.V1405M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV99523306; called by muse, mutect2
- OR51G1 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV58969732; called by muse, mutect2, varscan2
- PPBP | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.045); catalogued as COSV56019987; called by muse, mutect2, varscan2
- QSER1 | c.5143T>C p.W1715R (on ENST00000399302; = p.W1844R on NM_001076786.3) | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67901094; called by muse, mutect2, varscan2
- RANBP6 | c.214_215insGT p.A72Gfs*31 | Frame Shift Ins (INS) | VAF 38/140 reads (27%) | catalogued as COSV99424511; called by pindel, varscan2
- RAP2B | c.211T>A p.Y71N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100059201; called by muse, mutect2
- RMC1 | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.735); catalogued as rs771005240, COSV52572227; called by muse, varscan2
- SNRNP200 | c.3638A>G p.K1213R | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV60491679; called by muse, mutect2, varscan2
- SPECC1 | c.934T>C p.S312P | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV54961221; called by muse, mutect2, varscan2
- TAF1B | c.1602T>A p.N534K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.622); catalogued as COSV55157572; called by muse, mutect2, varscan2
- TCF20 | c.4559C>T p.T1520M | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs781578465, COSV100167087; called by muse, mutect2
- ITGB1BP1 | c.321_323del p.E109del | In Frame Del (DEL) | VAF 7/33 reads (21%) | called by pindel, varscan2
- TRIM2 | c.1994del p.G665Efs*11 (on ENST00000437508; = p.G692Efs*11 on NM_015271.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 61/158 reads (39%) | called by mutect2, pindel, varscan2
- USF3 | c.2638_2639del p.V880Ifs*4 | Frame Shift Del (DEL) | VAF 68/622 reads (11%) | called by mutect2, pindel, varscan2
- BEST3 | c.351C>T p.S117= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs779297098, COSV99876435; called by muse, mutect2, varscan2
- CREB3L1 | c.705G>A p.A235= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs545047399, COSV55831443; called by muse, mutect2
- FSHB | c.261T>C p.H87= | Silent (SNP) | VAF 19/163 reads (12%) | catalogued as COSV54222375; called by muse, mutect2, varscan2
- KCNAB3 | c.780G>A p.L260= | Silent (SNP) | VAF 42/72 reads (58%) | catalogued as rs1179543842, COSV58140835; called by muse, mutect2, varscan2
- L3MBTL3 | c.651G>A p.S217= | Silent (SNP) | VAF 64/554 reads (12%) | catalogued as rs1235743643, COSV62387065; called by muse, mutect2, varscan2
- LPCAT1 | c.801C>T p.N267= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV52039202; called by muse, mutect2, varscan2
- LRRIQ1 | c.3729T>C p.T1243= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs1478065393, COSV67833525; called by muse, mutect2, varscan2
- NOTCH3 | c.1752C>T p.D584= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs201207820, COSV54639291; ClinVar: benign; called by muse, mutect2
- PTPRT | c.3723G>A p.K1241= | Silent (SNP) | VAF 45/219 reads (21%) | catalogued as COSV61994856; called by muse, mutect2, varscan2
- TMEM159 | c.465C>T p.F155= | Silent (SNP) | VAF 58/276 reads (21%) | catalogued as rs939874083, COSV51785528; called by muse, mutect2, varscan2
- TRDC | c.219A>C p.S73= | Silent (SNP) | VAF 58/241 reads (24%) | called by muse, varscan2
- TSHZ3 | c.621C>T p.I207= | Silent (SNP) | VAF 102/744 reads (14%) | catalogued as COSV53675470; called by muse, mutect2, varscan2
- UBA6 | c.1485T>C p.V495= | Silent (SNP) | VAF 9/181 reads (5%) | catalogued as COSV100451999; called by muse, mutect2
- YIPF3 | c.813C>T p.P271= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100397185; called by muse, mutect2
- MIR20B | n.44A>G | RNA (SNP) | VAF 149/256 reads (58%) | called by muse, mutect2, varscan2
- SLC6A1 | c.-1C>T | 5'UTR (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99823331; called by muse, mutect2, varscan2
- ZNF493 | c.-132+7891A>G | Intron (SNP) | VAF 67/450 reads (15%) | catalogued as COSV60550549; called by muse, varscan2
